TCGA case TCGA-14-1823 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a515cf2d-e918-4958-9bf6-e611b425a97e

Demographics
Sex at birth: female; Race: white; Age at index: 58 years; Vital status: Dead; Days to death: 543 days (1.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 58.5 years (21,384 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Treatment dose: 8 Wafer.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 450 days (1.2 years); Number of cycles: 12; Treatment dose: 11,150 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 20 days; Days to treatment end: 450 days (1.2 years); Number of cycles: 12; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 70 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 140 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 378 days (1.0 years); Days to treatment end: 478 days (1.3 years); Treatment dose: 6,400 mg.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 58.9 years (21,524 days); Days to diagnosis: 140 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 140 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 140 days.
- Days to follow up: 543 days (1.5 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-1823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.2.
  Slide TCGA-14-1823-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 2.
  Slide TCGA-14-1823-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 2.
- Sample TCGA-14-1823-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-14-1823-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel Wafers.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 3: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Progression.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: Per enrollment form, patient had a prior diagnosis of a lower grade glioma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 543 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 543 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 140 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-1823-01A-01D-0591-01): tumor purity 0.64, ploidy 2.55, whole-genome doublings 1.
